Gene-level copy-number profile of tumor specimen ALCH-B27J-TTP1-A from ALCHEMIST case ALCH-B27J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.8 years (25,509 days).
Specimen ALCH-B27J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20e488b0-abce-472d-b627-f2795d86e49f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27J-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,814 have no estimate.
https://portal.gdc.cancer.gov/files/e1db991d-182a-4137-ab52-dcdf591de9a1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 547; copy number 2: 2,473; copy number 3: 3,401; copy number 4: 31,198; copy number 5: 13,166; copy number 6: 5,226; copy number 7: 1,241; copy number 8: 885; copy number 9: 303; copy number 10: 232; copy number 11: 83; copy number 12: 16; copy number 13: 4; copy number 14: 15; copy number 16: 1; copy number 17: 10; copy number 22: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 672 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes, copy number 12: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr2:61,187,463–61,538,741, 8 genes, copy number 9: USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3.
- chr2:62,673,851–64,019,428, 24 genes, copy number 10 (within-gene range 10–11): EHBP1, Y_RNA, AC092567.2, AC092567.1, RPS20P9, AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2, WDPCP, Metazoa_SRP, MTFR2P1, AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54.
- chr2:64,817,378–64,863,626, 4 genes, copy number 10: RN7SL341P, Y_RNA, AC007880.1, LINC01800.
- chr2:100,591,150–101,987,167, 25 genes, copy number 9–10: HMGN2P22, LINC01849, NANOGNBP1, LINC01868, AC092168.1, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, MAP4K4, LINC01127.
- chr2:102,311,502–102,452,565, 7 genes, copy number 9: IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1.
- chr3:167,735,243–167,950,292, 5 genes, copy number 9: SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3.
- chr3:169,613,510–169,869,935, 14 genes, copy number 9: AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr3:170,037,995–170,418,615, 10 genes, copy number 9–13: GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr3:171,941,607–172,401,669, 4 genes, copy number 9 (within-gene range 8–9): AC055714.1, FNDC3B, RPS27AP8, RN7SL141P.
- chr3:172,505,508–172,831,229, 13 genes, copy number 9–10: TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:177,010,719–177,767,379, 12 genes, copy number 9–11 (within-gene range 8–11): MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1.
- chr3:178,960,121–179,267,002, 7 genes, copy number 9–10: ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1.
- chr3:181,847,526–182,035,644, 4 genes, copy number 9: AC007547.2, AC007547.1, LINC01206, RN7SKP265.
- chr3:182,446,970–182,617,810, 5 genes, copy number 9: LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8.
- chr3:183,613,620–184,135,238, 22 genes, copy number 9 (within-gene range 8–9): AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2.
- chr3:184,230,429–184,249,548, 3 genes, copy number 9 (within-gene range 8–9): VWA5B2, MIR1224, ALG3.
- chr3:185,582,496–185,980,872, 7 genes, copy number 10: SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P.
- chr3:186,772,589–186,807,058, 10 genes, copy number 10–11 (within-gene range 7–11): GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4.
- chr3:186,842,704–187,078,553, 5 genes, copy number 9: ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1.
- chr3:188,562,238–188,947,639, 3 genes, copy number 9 (within-gene range 8–9): LPP-AS1, MIR28, TPRG1-AS1.
- chr3:189,631,389–190,122,437, 4 genes, copy number 9 (within-gene range 8–10): TP63, AC078809.1, MIR944, P3H2.
- chr3:190,514,051–190,716,399, 6 genes, copy number 9: IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4.
- chr3:196,027,183–196,736,007, 35 genes, copy number 9–10: TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P.
- chr3:196,867,856–196,943,543, 5 genes, copy number 11: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2.
- chr3:197,042,560–197,303,755, 3 genes, copy number 9 (within-gene range 9–11): DLG1, MIR4797, DLG1-AS1.
- chr3:197,634,315–198,123,232, 23 genes, copy number 9: AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr8:42,101,318–42,271,266, 7 genes, copy number 9: AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr8:80,484,561–80,526,265, 3 genes, copy number 9: AC009812.1, Y_RNA, ZBTB10.
- chr9:134,849,298–134,849,682, 3 genes, copy number 10: MIR3689C, MIR3689A, MIR3689D1.
- chr12:12,813,316–12,876,107, 4 genes, copy number 9 (within-gene range 8–9): DDX47, AC007215.1, AC007688.2, RPL13AP20.
- chr12:91,871,122–91,906,187, 3 genes, copy number 11: AC090049.2, LINC02404, AC090049.1.
- chr15:20,073,699–20,096,029, 2 genes, copy number 11: BCAR1P1, RN7SL584P.
- chr16:32,715,931–32,788,944, 8 genes, copy number 22: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr17:63,471,604–65,227,703, 81 genes, copy number 10–17 (broad region; genes not listed).
- chr17:66,197,693–69,060,949, 74 genes, copy number 9–10 (broad region; genes not listed).
- chr17:69,244,311–70,368,916, 17 genes, copy number 9–11 (within-gene range 8–11): ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr17:72,627,231–73,092,712, 6 genes, copy number 9 (within-gene range 8–9): RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr17:74,521,174–76,861,836, 140 genes, copy number 9–11 (broad region; genes not listed).
- chr18:63,367,328–63,505,085, 6 genes, copy number 9 (within-gene range 6–9): AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
